Gene-level copy-number profile of tumor specimen TCGA-DD-AAEH-01A from TCGA case TCGA-DD-AAEH, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 73.6 years (26,894 days).
Specimen TCGA-DD-AAEH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.e5a96378-7a2c-4603-9ef9-c0f876511bb4.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DD-AAEH-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 360 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/38713318-c234-4121-9442-d8c9bc9fc31c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1,728; copy number 1: 4,534; copy number 2: 47,650; copy number 3: 4,802; copy number 4: 555; copy number 5: 991; copy number 6: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DD-AAEH-01A-11D-A40Q-01): tumor purity 0.69, ploidy 2.04, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:34,489,002–34,495,900, 2 genes: HNRNPLP2, FSCN1P1.
- chr22:32,188,400–32,188,487, 1 gene: AL008723.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 994 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:221,330,080–221,336,489, 1 gene, copy number 6: LINC02817.
- chr6:2,663,629–29,431,967, 604 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr6:38,715,311–39,030,792, 1 gene, copy number 5 (within-gene range 4–5): DNAH8.
- chr6:38,923,029–57,961,501, 376 genes, copy number 5 (within-gene range 5–7) (broad region; genes not listed).
- chr6:57,967,687–58,121,029, 3 genes, copy number 5: GAPDHP15, AL390237.1, RBBP4P4.
- chr19:4,402,640–4,502,208, 9 genes, copy number 5: CHAF1A, AC011498.3, UBXN6, MIR4746, AC011498.2, AC011498.7, AC011498.6, AC011498.1, HDGFL2.

Autosomal genes at a single copy (total copy number 1): 4,496. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
